Somatic mutation profile of tumor specimen TCGA-CV-6003-01A (aliquot TCGA-CV-6003-01A-11D-1683-08) from TCGA case TCGA-CV-6003, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.9 years (18,600 days).
Specimen TCGA-CV-6003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6695c219-efe5-44cb-a9a6-35496a4e9551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6003-11A (Solid Tissue Normal), aliquot TCGA-CV-6003-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69d8e110-7509-4dc8-a300-9cd54dac0a86

The open-access MAF lists 101 somatic variants for this specimen: 80 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Nonsense Mutation 8, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, varscan2
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 37/49 reads (76%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABTB1 | c.306C>G p.D102E | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99230137; called by muse, mutect2, varscan2
- AC004593.2 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56103511, COSV99766098; called by muse, mutect2, varscan2
- ATP7A | c.2140T>G p.L714V | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV58446987; called by muse, mutect2, varscan2
- BCORL1 | c.3995G>A p.R1332Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005100760, COSV54404511; called by muse, mutect2, varscan2
- BRPF1 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs775663066, COSV100121425; called by muse, mutect2, varscan2
- BTNL8 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746524916, COSV99180585; called by muse, mutect2, varscan2
- CASC3 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV99230031; called by muse, mutect2, varscan2
- CASK | c.2109G>C p.K703N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.448); catalogued as COSV100587797; called by muse, mutect2, varscan2
- CCNJ | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs769713207, COSV56443009; called by muse, mutect2, varscan2
- CDH7 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760397263, COSV59885790; called by muse, mutect2, varscan2
- CFAP54 | c.4755_4758del p.T1586Ffs*23 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1246585689; called by mutect2, pindel, varscan2
- CFAP54 | c.6200G>T p.C2067F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV100733343, COSV61573445; called by muse, mutect2, varscan2
- CNN3 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV100930961; called by muse, mutect2, varscan2
- CPS1 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147443001; called by muse, mutect2, varscan2
- CUBN | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64707939; called by muse, mutect2, varscan2
- DRD4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1231135505, COSV99448909; called by muse, mutect2, varscan2
- DSCC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV100558416; called by muse, mutect2, varscan2
- EHD1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs137874978; called by muse, mutect2, varscan2
- EHMT2 | c.43-1G>A p.X15_splice | Splice Site (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100977046; called by muse, mutect2
- ESRP1 | c.1443G>C p.L481F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100619659; called by muse, mutect2
- FAT4 | c.13307C>T p.P4436L | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs760631255, COSV58677974, COSV58693071; called by muse, mutect2, varscan2
- FGD1 | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV100911261; called by muse, mutect2
- FGFR4 | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99450947; called by muse, mutect2, varscan2
- FGL2 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99593160; called by muse, mutect2, varscan2
- FOCAD | c.4603G>A p.G1535R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.916); catalogued as COSV100620702; called by muse, mutect2, varscan2
- GABRA1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99196287; called by muse, mutect2, varscan2
- GHITM | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100930141; called by muse, mutect2, varscan2
- HDAC7 | c.1577C>T p.S526L (on ENST00000427332; = p.S565L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs150532318; called by muse, varscan2
- IGF1R | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1409058783, CM1211669, COSV51407980, COSV99163101; ClinVar: protective; called by mutect2, varscan2
- INPPL1 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 125/259 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.879); catalogued as rs1253875635, COSV53354041; called by muse, mutect2, varscan2
- ITGA3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99144260; called by muse, mutect2, varscan2
- ITGB1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as rs749899655, COSV100172022; called by muse, mutect2, varscan2
- KCNG4 | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100377188; called by muse, mutect2, varscan2
- KCNK4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100107849; called by muse, mutect2, varscan2
- KDM5A | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV101239067; called by muse, mutect2, varscan2
- MAMDC4 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.862); catalogued as rs368772199; called by muse, varscan2
- MCHR2 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV56001981, COSV99912714; called by muse, mutect2, varscan2
- MICAL2 | c.2692C>A p.H898N | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV99818391; called by muse, mutect2, varscan2
- MYCT1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773225210, COSV65891270; called by muse, mutect2, varscan2
- NELFCD | c.1559C>T p.P520L (on ENST00000602795; = p.P502L on NM_198976.4) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53883169, COSV99413747; called by muse, mutect2, varscan2
- NLGN4X | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52040440; called by muse, mutect2, varscan2
- NNT | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.324); catalogued as COSV99239601; called by muse, mutect2, varscan2
- NOTCH2 | c.537T>A p.C179* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as COSV56705599, COSV56709780; called by muse, mutect2, varscan2
- OCRL | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100843573; called by muse, mutect2, varscan2
- OR6B1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1400090577, COSV101281649; called by muse, mutect2, varscan2
- PARD6G | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100783477; called by muse, mutect2
- PCDH15 | c.5159C>G p.S1720C (on ENST00000644397 / NM_001354429.2; = p.S1662C on NM_001142771.2) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as rs1387609945, COSV100905793; called by muse, mutect2, varscan2
- PCDHA13 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV56544539; called by muse, mutect2, varscan2
- PCDHA5 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV65353786; called by muse, mutect2, varscan2
- PCDHGB1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749871543, COSV53915242; called by muse, mutect2, varscan2
- PCNX1 | c.4403G>T p.W1468L | Missense Mutation (SNP) | VAF 120/153 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99457294; called by muse, mutect2, varscan2
- PDCL3 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV51808916, COSV99959714; called by muse, mutect2
- RNASEL | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs766020877, COSV62376692; called by muse, mutect2, varscan2
- RNMT | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054955; called by muse, mutect2, varscan2
- RNPS1 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as rs770188560, COSV100067673; called by muse, mutect2, varscan2
- ROS1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100877717; called by muse, mutect2
- RPH3A | c.1855G>A p.E619K (on ENST00000389385 / NM_001143854.2; = p.E615K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV101231893; called by muse, mutect2
- SCN1A | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.078); catalogued as CM093369, COSV100322206, COSV57668765; called by muse, mutect2, varscan2
- SENP2 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99958189; called by muse, mutect2, varscan2
- SPANXN1 | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 17/106 reads (16%) | catalogued as COSV65122450; called by muse, mutect2, varscan2
- SPEN | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1256467004, COSV101005625; called by muse, mutect2, varscan2
- TANGO6 | c.2958G>C p.Q986H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99937007; called by muse, mutect2
- TBX22 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100960958; called by muse, mutect2, varscan2
- TCEA3 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101508346; called by muse, mutect2, varscan2
- TFAP2E | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100951515; called by muse, mutect2, varscan2
- USP11 | c.1520G>A p.R507H (on ENST00000218348; = p.R464H on NM_001371072.1) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs774213603, COSV99511189; called by muse, mutect2, varscan2
- ZCCHC13 | c.399C>A p.C133* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100272593, COSV59866657; called by muse, mutect2, varscan2
- ZMYND11 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.669); catalogued as rs759027665, COSV100556934, COSV59080986; called by muse, mutect2, varscan2
- ZNF641 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV56390088; called by muse, mutect2, varscan2
- ZNF804A | c.2753T>C p.V918A | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100170256; called by muse, mutect2, varscan2
- ZNF81 | c.387A>T p.L129F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100096234; called by muse, mutect2, varscan2
- ZNFX1 | c.4622C>G p.T1541S | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV100872647; called by muse, mutect2, varscan2
- AJUBA | c.1010_1024del p.T337_C341del | In Frame Del (DEL) | VAF 63/92 reads (68%) | called by mutect2, pindel
- IMP3 | c.455_456dup p.S153Afs*20 | Frame Shift Ins (INS) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- RBM5 | c.883_884del p.Q295Efs*9 | Frame Shift Del (DEL) | VAF 26/53 reads (49%) | called by mutect2, pindel, varscan2
- RTL9 | c.489_490del p.E163Dfs*25 | Frame Shift Del (DEL) | VAF 18/188 reads (10%) | called by pindel, varscan2
- TP63 | c.493dup p.I165Nfs*33 | Frame Shift Ins (INS) | VAF 45/117 reads (38%) | called by mutect2, pindel, varscan2
- ADGRG3 | c.1395G>A p.A465= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs758757966, COSV100342689; called by muse, mutect2, varscan2
- AP2B1 | c.2202G>A p.G734= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as rs1206491703; called by muse, mutect2, varscan2
- CDH9 | c.1848C>T p.L616= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs541154525, COSV99155508; called by muse, mutect2, varscan2
- DICER1 | c.3696C>T p.S1232= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as rs767516330, COSV100602566; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDPD5 | c.1470C>T p.I490= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV61130905; called by muse, mutect2, varscan2
- HSPG2 | c.8769G>A p.L2923= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101013556; called by muse, mutect2, varscan2
- HYAL4 | c.1182G>A p.A394= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs138391454; called by muse, mutect2, varscan2
- KRT7 | c.198C>T p.V66= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100081815; called by muse, mutect2, varscan2
- MAGEC3 | c.42T>C p.S14= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV100026138, COSV53578299; called by muse, mutect2
- MCF2L | c.1173G>A p.L391= (on ENST00000375608; = p.L359= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs1285129479, COSV100983013; called by muse, mutect2, varscan2
- MRPL17 | c.15C>G p.V5= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs769434741, COSV99996934; called by muse, mutect2
- NAV2 | c.6330G>A p.E2110= (on ENST00000396087 / NM_001244963.2; = p.E2051= on NM_145117.5) | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs1419451824, COSV100217667; called by muse, mutect2
- NEFH | c.2721G>A p.E907= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100151843; called by muse, mutect2
- OR5AR1 | c.921A>G p.K307= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100265808; called by muse, mutect2
- PYGB | c.1479G>T p.L493= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV99405465; called by muse, mutect2, varscan2
- RBAK | c.198G>A p.P66= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs576821880, COSV62332999; called by muse, mutect2, varscan2
- SALL1 | c.2130C>T p.I710= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV99190646; called by muse, mutect2, varscan2
- SVEP1 | c.7389C>G p.L2463= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV52838797, COSV99929837, COSV99930084; called by muse, mutect2, varscan2
- TCEAL6 | c.114G>A p.A38= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs782633338, COSV65654267; called by muse, mutect2
- ZNF646 | c.3654C>T p.L1218= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99762672; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/55 reads (11%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
